Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NK, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NK-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, squamous cell NOS
Site ^{CSE} Esophagus, middle third
^{path} Esophagus, cervical
8070/3
C15.4
C15.0
QJ 11/7/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old with two month history of mid retrosternal dysphagia (+) 20 pd wt.
loss over past month. Clinical Diagnosis: Esophageal cancer. Operative
Procedure: THE. 1) Cervical esophagus. 2) Cervical esophageal margin. 3) Mid
right paraesophageal LN. 4) Left gastric LN, celiac angle.

PROCEDURE:

VERIFIED BY:

1. "Cervical esophagus" Received in formalin in a large container is a 12.2 cm
segment of previously opened esophagus with a tan-brown unremarkable
adventitial surface. Upon opening the mucosa surface is white-tan, smooth and
glistening with the exception of a 3 x 2 cm ulcerating lesion (C's depth: .1
cm) that involves approximately 50% of the circumference. The lesion is 2.5 cm
away from the stapled margin. Specimen inked blue and sectioned. Grossly the
adventitial surface under the lesion is firm and indurated and it appears that
the tumor mass involves the whole circumference of the esophagus underneath
the mucosa. The tumor extends into the adventitia.

1A. Margin closest to tumor.

1B. Margin furthest away from tumor.

1C-F. One linear section of esophagus from margin nearest tumor to distal
margin.

1G. Possible lymph nodes.

2. "Cervical esophageal margin" Received in formalin in a small container is a
1 cm segment of esophagus with staples at one end. Mucosal and serosal surface
are grossly unremarkable.

3. "Left gastric lymph node taken from celiac origin" Received in formalin in
a small container is a yellow-tan 0.6 cm diameter soft tissue mass. Bisected.

4. "Mid-right paraesophageal lymph node" Received in formalin in a small
container is a brown-tan 0.5 cm soft tissue bit.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Type of carcinoma: Squamous cell carcinoma
Depth of invasion: Periesophageal soft tissue..
Number of positive lymph nodes: 0/14
Extranodal metastasis: Unknown.
Pattern of invasion: Infiltrative.
Esophageal and gastric resection margins involved: No
Deep resection margin involved: Yes.
TNM classification: T3 N0 Mx

PROCEDURE:

VERIFIED BY:

1 & 2. Esophagus, transhiatal esophagectomy: Invasive well differentiated squamous cell carcinoma. The tumor traverses the muscularis propria and extends into the periesophageal soft tissue. The tumor is present at the inked periesophageal soft tissue margin. The proximal and distal surgical margins are negative. Six periesophageal lymph nodes are negative for neoplasm. See template.

3. Left gastric lymph nodes, excision: Six lymph nodes negative for malignancy.

4. Mid right periesophageal lymph node, excision: One lymph node negative for neoplasm.

, , M.D.

I, M.D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 3d8c33ba-cfd8-48e0-9a83-bb8aa0c1b42e (TCGA-L5-A8NK.2249DA6D-2344-4D15-8D0C-2FB44CC2818E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).